Gene-level copy-number profile of tumor specimen TCGA-DD-AACB-01A from TCGA case TCGA-DD-AACB, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 74.2 years (27,103 days).
Specimen TCGA-DD-AACB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.c767240e-5c19-40cf-80ca-b9bb141f4dae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DD-AACB-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/24c69f5f-f234-4f99-96a5-b49695a56a3f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 875; copy number 2: 12,158; copy number 3: 21,892; copy number 4: 21,285; copy number 5: 351; copy number 6: 1,541; copy number 7: 99; copy number 9: 300; copy number 11: 439; copy number 12: 830; copy number 13: 27; copy number 15: 23.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DD-AACB-01A-11D-A40Q-01): tumor purity 0.67, ploidy 3.29, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,718 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:63,193,072–65,707,226, 23 genes, copy number 15 (within-gene range 2–15): AL450346.1, FKBP1C, SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1.
- chr8:41,653,220–41,896,762, 1 gene, copy number 7 (within-gene range 3–7): ANK1.
- chr8:41,803,349–145,066,685, 1,594 genes, copy number 7–12 (broad region; genes not listed).
- chr11:67,317,871–69,704,022, 100 genes, copy number 7–13 (within-gene range 3–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 875. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
